Somatic mutation profile of tumor specimen TCGA-FU-A3WB-01A (aliquot TCGA-FU-A3WB-01A-11D-A22X-09) from TCGA case TCGA-FU-A3WB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 43.3 years (15,833 days).
Specimen TCGA-FU-A3WB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 668803aa-e09b-461b-93d0-a6886accd30f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3WB-10A (Blood Derived Normal), aliquot TCGA-FU-A3WB-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ac39a77-bf7a-476c-b96e-8d351ce50614

The open-access MAF lists 74 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 4, Intron 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/48 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANLN | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs983478407, COSV99732808; called by muse, mutect2
- APBB1IP | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100774288, COSV63304588; called by muse, mutect2, varscan2
- APOL5 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV50766337, COSV50766937; called by muse, mutect2, varscan2
- ARMC5 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV51656694; called by muse, mutect2, varscan2
- ATP11B | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV60029785, COSV60033853; called by muse, mutect2, varscan2
- ATP8B3 | c.3419C>G p.T1140S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV59549315; called by muse, mutect2, varscan2
- C2orf16 | c.3562G>A p.V1188I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199693170, COSV62678684; called by muse, mutect2, varscan2
- CDC25B | c.1072G>A p.E358K (on ENST00000245960 / NM_021873.3; = p.E344K on NM_004358.4) | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV55659993; called by muse, mutect2, varscan2
- CEP126 | c.1314G>C p.E438D | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV54824085, COSV54831410; called by muse, mutect2, varscan2
- CEP126 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.784); catalogued as rs1210703485, COSV54830027, COSV54831424; called by muse, mutect2, varscan2
- CEP126 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54831437; called by muse, mutect2, varscan2
- CEP126 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV54831445; called by muse, mutect2, varscan2
- CREBBP | c.3793del p.D1265Ifs*11 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV99269167; called by mutect2, pindel, varscan2
- EFHB | c.515A>C p.E172A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.142); catalogued as COSV55554353; called by muse, varscan2
- EPHA4 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs750627059, COSV56033405, COSV56045308; called by muse, mutect2, varscan2
- FAM3A | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs181188384, COSV59195164; called by muse, mutect2, varscan2
- FCGRT | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs767260789, COSV54542974; called by muse, mutect2, varscan2
- GPC5 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs1449780201, COSV65632007; called by muse, mutect2, varscan2
- GPLD1 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV57761553; called by muse, mutect2, varscan2
- HECW1 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV67841189; called by muse, mutect2, varscan2
- HMGXB4 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757502367, COSV53333925; called by muse, mutect2, varscan2
- IGLV3-10 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs531483201; called by muse, mutect2, varscan2
- KIAA1210 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV68180571; called by muse, mutect2
- KRT6A | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100416639, COSV58108123; called by muse, mutect2, varscan2
- LPIN2 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753664055, COSV55244778; called by muse, mutect2, varscan2
- LRRTM3 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1401377000, COSV63661689; called by muse, mutect2, varscan2
- MAGEL2 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV58569429; called by muse, mutect2, varscan2
- MCF2L2 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61062524; called by muse, mutect2, varscan2
- MMP15 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs757678463, COSV54681812; called by muse, mutect2, varscan2
- MOV10L1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs41311449, COSV99435080; called by muse, mutect2, varscan2
- OR4N2 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV60055440; called by muse, varscan2
- PCDHB10 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs782317669, COSV53375623; called by muse, mutect2, varscan2
- PCLAF | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); catalogued as COSV55541360; called by muse, mutect2, varscan2
- PFDN5 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs201325659, COSV54477259; called by muse, mutect2, varscan2
- PLIN3 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs577339133, COSV55734652; called by muse, mutect2, varscan2
- PNISR | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV65080909; called by muse, mutect2, varscan2
- POLD1 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs140707092, COSV70957044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.817); catalogued as rs1267693319, COSV58246316; called by mutect2, varscan2
- RASGRP2 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV51230653; called by muse, mutect2, varscan2
- RPL8 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52800207; called by muse, mutect2, varscan2
- RTTN | c.4835C>T p.S1612F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV55348178, COSV55352920; called by muse, mutect2, varscan2
- SETD1A | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353657; called by muse, mutect2, varscan2
- SLC26A4 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55920538; called by muse, mutect2, varscan2
- SLCO5A1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs986356925, COSV52669302; called by muse, mutect2, varscan2
- SMARCA1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200644579, COSV64414092; called by muse, mutect2, varscan2
- SMC1B | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs746547020, COSV62533808; called by muse, mutect2, varscan2
- SMCHD1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV55270004; called by muse, mutect2, varscan2
- SNAI3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1353848779, COSV60003518; called by muse, mutect2, varscan2
- THSD7B | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV55742859; called by muse, mutect2, varscan2
- TMPRSS11D | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as COSV52226921; called by muse, mutect2, varscan2
- TRANK1 | c.8446G>A p.E2816K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV57139346; called by muse, mutect2, varscan2
- ZBTB16 | c.1568G>C p.C523S | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60100276; called by muse, mutect2, varscan2
- ZNF311 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV65853464; called by muse, mutect2, varscan2
- PM20D2 | c.1142_1143insTACT p.E383Hfs*2 | Frame Shift Ins (INS) | VAF 37/102 reads (36%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.254_273delinsGTGA p.V85Gfs*115 | Frame Shift Del (DEL) | VAF 26/50 reads (52%) | called by pindel, varscan2*
- ACTRT1 | c.528C>T p.H176= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as rs140288728, COSV100947550, COSV100947755; called by muse, mutect2, varscan2
- ARMCX5 | c.1674C>G p.L558= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV55767811; called by muse, mutect2, varscan2
- ATP1A3 | c.2826C>A p.T942= (on ENST00000545399 / NM_001256214.2; = p.T929= on NM_152296.5) | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- CRACD | c.1146G>A p.P382= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs757799385, COSV99949964; called by muse, mutect2, varscan2
- EXOC3L4 | c.63G>A p.E21= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1204357615, COSV66296034; called by muse, mutect2, varscan2
- FER1L5 | c.5502G>A p.Q1834= (on ENST00000623019; = p.Q1798= on NM_001293083.2) | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV99383621; called by muse, mutect2, varscan2
- FJX1 | c.1251C>T p.L417= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV58554204; called by muse, mutect2, varscan2
- HIVEP2 | c.7335A>G p.L2445= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV50074559; called by muse, mutect2, varscan2
- MROH1 | c.2916C>T p.F972= | Silent (SNP) | VAF 74/166 reads (45%) | called by muse, mutect2, varscan2
- PTPN22 | c.237T>C p.D79= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63086875; called by muse, mutect2, varscan2
- RTP5 | c.117G>A p.L39= | Silent (SNP) | VAF 111/147 reads (76%) | catalogued as COSV58322252; called by muse, mutect2, varscan2
- SERPINH1 | c.615C>T p.F205= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV63998742; called by muse, mutect2, varscan2
- TTR | c.312C>T p.I104= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs1291187509, COSV52702146; called by muse, mutect2, varscan2
- ZBTB20 | c.1764C>T p.T588= (on ENST00000474710 / NM_001164342.2; = p.T515= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs142230895; called by muse, mutect2, varscan2
- ZFR2 | c.879G>A p.Q293= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV53603914; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23145C>T | Intron (SNP) | VAF 14/210 reads (7%) | catalogued as rs781604404, COSV61421340; called by muse, mutect2
- WNK1 | c.2140-3321C>T | Intron (SNP) | VAF 20/47 reads (43%) | catalogued as rs1013040631, COSV60025061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
